Somatic mutation profile of tumor specimen 0DGOAR from CCDI case PBBSUN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 1.5 years (559 days).
Specimen 0DGOAR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e98d5b3-e94c-49a1-a627-76725d19c151.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGOBF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2fc81a2-0f3a-4e47-9125-b4e6060e777a

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 2, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FMN2 | c.2395G>A p.D799N | Missense Mutation (SNP) | VAF 188/595 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as rs267598445, COSV60429711; called by muse, mutect2, varscan2
- KLHL13 | c.1112C>A p.S371* | Nonsense Mutation (SNP) | VAF 193/736 reads (26%) | catalogued as COSV53245217; called by muse, mutect2, varscan2
- LCT | c.1085T>G p.I362S | Missense Mutation (SNP) | VAF 71/596 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DNAH3 | c.543G>A p.T181= | Silent (SNP) | VAF 58/448 reads (13%) | catalogued as rs745740403; called by muse, mutect2, varscan2
- GRIK5 | c.2758C>A p.R920= | Silent (SNP) | VAF 14/294 reads (5%) | called by muse, mutect2
